Gene-level copy-number profile of tumor specimen TCGA-BR-A4J8-01A from TCGA case TCGA-BR-A4J8, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.3 years (26,048 days).
Specimen TCGA-BR-A4J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d313fe97-b580-4f7c-8b11-42ac3575ecfa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4J8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6ca9cc3-488e-4027-89d9-c86d5224906e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,544; copy number 2: 22,787; copy number 3: 23,247; copy number 4: 8,487; copy number 5: 1,824; copy number 7: 502; copy number 8: 94; copy number 9: 216; copy number 10: 81; copy number 11: 30; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4J8-01A-11D-A253-01): tumor purity 0.59, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:91,108,023–91,112,790, 1 gene: AC004054.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 924 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:23,971,879–25,057,073, 30 genes, copy number 11: AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2.
- chr6:29,329,626–31,717,918, 216 genes, copy number 9 (broad region; genes not listed).
- chr6:41,905,354–43,842,625, 81 genes, copy number 10 (within-gene range 1–10) (broad region; genes not listed).
- chr6:52,977,948–53,208,697, 13 genes, copy number 7–8: GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1.
- chr6:57,855,891–65,707,226, 50 genes, copy number 7 (within-gene range 4–7): AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr6:67,210,408–67,210,480, 1 gene, copy number 14: AL591004.1.
- chr20:87,250–16,053,197, 291 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr20:15,892,355–26,251,546, 242 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
